Somatic mutation profile of tumor specimen ALCH-B1WG-TTP1-A (aliquot ALCH-B1WG-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1WG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.6 years (23,949 days).
Specimen ALCH-B1WG-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53ea7d69-315b-4a37-837c-5fd46e4042ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1WG-NB1-A (Blood Derived Normal), aliquot ALCH-B1WG-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2a533ec-94a6-4cc4-ab5a-f2f27a6f95f3

The open-access MAF lists 380 somatic variants for this specimen: 251 protein-altering or splice-affecting, 83 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 203, Silent 83, Intron 20, Frame Shift Del 17, Nonsense Mutation 14, Splice Site 11, 5'UTR 7, 5'Flank 6, 3'UTR 6, RNA 5, Splice Region 3, Frame Shift Ins 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 166/266 reads (62%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCG8 | c.691C>G p.P231A | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM012313; called by muse, mutect2, varscan2
- ANKRD26 | c.1903G>T p.G635W | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV101063335; called by muse, mutect2, varscan2
- APBA2 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 100/206 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as COSV68789154; called by muse, mutect2, varscan2
- ASIC2 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 61/351 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1338888402, COSV63295964; called by muse, mutect2, varscan2
- ATAD2 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99784724; called by muse, mutect2
- ATAD2 | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 22/388 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54883461; called by muse, mutect2
- ATM | c.7280T>G p.L2427R | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1555122272, COSV53729082, COSV53759952; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.7629+1G>T p.X2543_splice | Splice Site (SNP) | VAF 37/214 reads (17%) | catalogued as COSV53727963; called by muse, mutect2, varscan2
- ATRNL1 | c.3397T>G p.F1133V | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58084727; called by muse, mutect2, varscan2
- AXIN2 | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1488655314; ClinVar: uncertain significance; called by muse, mutect2
- B4GALT3 | c.940T>A p.W314R | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60526403; called by muse, mutect2
- CACNG7 | c.283+1G>A p.X95_splice | Splice Site (SNP) | VAF 68/153 reads (44%) | catalogued as COSV55812879; called by muse, mutect2, varscan2
- CARMIL2 | c.1808G>T p.R603L | Missense Mutation (SNP) | VAF 139/309 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV58030902, COSV58034294; called by muse, mutect2, varscan2
- CDH12 | c.2117C>G p.P706R | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs756028192; called by muse, mutect2, varscan2
- CDHR4 | c.1360G>T p.E454* | Nonsense Mutation (SNP) | VAF 73/303 reads (24%) | catalogued as COSV58525966; called by muse, mutect2, varscan2
- CHAT | c.1663G>T p.E555* | Nonsense Mutation (SNP) | VAF 99/596 reads (17%) | catalogued as rs757303526, CM119380; called by muse, varscan2
- CHRM5 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV67248139; called by muse, mutect2, varscan2
- CROCC2 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.228); catalogued as rs560728518; called by muse, mutect2, varscan2
- DSG1 | c.3029C>A p.A1010D | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV99936607; called by muse, mutect2, varscan2
- DYSF | c.2218C>A p.L740M | Missense Mutation (SNP) | VAF 181/543 reads (33%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); catalogued as COSV50307009; called by muse, mutect2, varscan2
- EIF4G3 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs768975773; called by muse, mutect2, varscan2
- EXOC7 | c.257A>G p.H86R | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs749789076; called by muse, mutect2, varscan2
- FMN2 | c.4534G>C p.D1512H | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100147037; called by muse, mutect2
- FRG2B | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV71042772, COSV71044237; called by muse, varscan2
- GABRQ | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs782073292, COSV64781315, COSV64781672; called by muse, mutect2, varscan2
- GALNT12 | c.1721G>C p.W574S | Missense Mutation (SNP) | VAF 97/242 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780798931; called by muse, mutect2, varscan2
- GPR158 | c.3447G>T p.E1149D | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100894000; called by muse, mutect2, varscan2
- GPR61 | c.367G>T p.V123L | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs757182741; called by muse, mutect2, varscan2
- GRIK5 | c.1376G>T p.R459L | Missense Mutation (SNP) | VAF 48/339 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.647); catalogued as COSV53477519; called by muse, mutect2, varscan2
- GZF1 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV57638093; called by muse, mutect2, varscan2
- HAPLN4 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV52269756; called by muse, mutect2, varscan2
- HGF | c.125T>A p.F42Y | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1452813921; called by muse, mutect2, varscan2
- HRNR | c.3776G>A p.G1259D | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as rs201459138; called by mutect2, varscan2
- IL17C | c.175G>C p.G59R | Missense Mutation (SNP) | VAF 99/164 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as rs767994930; called by muse, mutect2, varscan2
- INPP5J | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV58515020; called by muse, mutect2, varscan2
- JPH2 | c.1823C>A p.T608K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV65904793; called by muse, mutect2, varscan2
- KBTBD13 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs750168932; called by muse, mutect2, varscan2
- KIF11 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as rs1276986880, COSV53271421; called by muse, mutect2, varscan2
- KIF3C | c.1305G>T p.E435D | Missense Mutation (SNP) | VAF 87/202 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs757127949, COSV53097573; called by muse, mutect2, varscan2
- KSR2 | c.1164C>A p.F388L | Missense Mutation (SNP) | VAF 104/349 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV56668881; called by muse, mutect2, varscan2
- LHX8 | c.1015G>C p.G339R | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.548); catalogued as COSV53957785; called by muse, mutect2, varscan2
- LRRIQ1 | c.4222G>A p.G1408S | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67835934; called by muse, mutect2, varscan2
- MS4A1 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 49/255 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100619388, COSV61942914; called by muse, mutect2, varscan2
- MTF1 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1368467719, COSV65962668; called by muse, mutect2, varscan2
- MUC16 | c.18779C>T p.A6260V | Missense Mutation (SNP) | VAF 73/145 reads (50%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs772779309; called by muse, mutect2, varscan2
- MYO1G | c.2526+1G>T p.X842_splice | Splice Site (SNP) | VAF 25/77 reads (32%) | catalogued as rs1024754609; called by muse, mutect2, varscan2
- NAV3 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 51/266 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV57072868, COSV57104963; called by muse, mutect2, varscan2
- NRP1 | c.2696A>G p.Y899C | Missense Mutation (SNP) | VAF 90/218 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769226149; called by muse, mutect2, varscan2
- NSD1 | c.3050C>G p.T1017S | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.024); catalogued as COSV100728514; called by muse, mutect2, varscan2
- OBSCN | c.8912G>T p.R2971L | Missense Mutation (SNP) | VAF 150/482 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs202236984, COSV52825882; called by muse, mutect2, varscan2
- OR2L2 | c.85C>A p.L29I | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV63550740; called by muse, mutect2, varscan2
- OR2T33 | c.64C>A p.H22N | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.691); catalogued as COSV58814979, COSV58817980; called by muse, mutect2, varscan2
- OR5D13 | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV62335643; called by muse, mutect2, varscan2
- OR5D16 | c.180del p.M61Cfs*22 | Frame Shift Del (DEL) | VAF 25/82 reads (30%) | catalogued as COSV65721467; called by mutect2, pindel, varscan2
- PCDH10 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV52102266, COSV99994165; called by muse, mutect2, varscan2
- PDZD2 | c.1666-1G>C p.X556_splice | Splice Site (SNP) | VAF 26/155 reads (17%) | catalogued as rs1197153921; called by muse, mutect2, varscan2
- PHACTR3 | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 91/255 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV63027472, COSV63034166; called by muse, mutect2, varscan2
- PLCB4 | c.2164G>T p.V722L | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV53796321, COSV99059197; called by muse, mutect2, varscan2
- PPFIA3 | c.3408G>C p.E1136D | Missense Mutation (SNP) | VAF 70/315 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.76); catalogued as rs1196326418; called by muse, mutect2, varscan2
- PRDM9 | c.2273G>A p.R758H | Missense Mutation (SNP) | VAF 135/444 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs1450853481, COSV57004243; called by muse, varscan2
- PRKCG | c.1763G>A p.G588E | Missense Mutation (SNP) | VAF 41/271 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as rs1568762863, COSV54723886, COSV99669142; called by muse, mutect2, varscan2
- RAPGEFL1 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 53/279 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV52863091; called by muse, mutect2, varscan2
- REV3L | c.1502C>T p.S501L | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as rs1328943223; called by muse, mutect2, varscan2
- RYR2 | c.3342G>T p.R1114S | Missense Mutation (SNP) | VAF 103/426 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs1040630830; called by muse, mutect2, varscan2
- RYR3 | c.2599A>G p.K867E | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.437); catalogued as rs752228470, COSV66796981; ClinVar: likely benign; called by muse, mutect2
- SCGB2A1 | c.16G>T p.V6F | Missense Mutation (SNP) | VAF 35/236 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as rs1228680224; called by muse, mutect2, varscan2
- SCN11A | c.1916G>A p.R639Q | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs866651197; called by muse, mutect2, varscan2
- SESTD1 | c.1577G>C p.R526T | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as COSV58931617; called by muse, mutect2, varscan2
- SLC17A6 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.101); catalogued as rs746005926; called by muse, mutect2, varscan2
- SLC9A9 | c.982G>T p.E328* | Nonsense Mutation (SNP) | VAF 66/370 reads (18%) | catalogued as COSV100343577; called by muse, mutect2, varscan2
- SLITRK3 | c.323T>A p.L108H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53854366; called by muse, mutect2, varscan2
- SP140 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763966598, COSV59451528; called by muse, mutect2, varscan2
- STAG3 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 29/317 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs369812552, COSV100426262; called by muse, mutect2
- TBXAS1 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 230/644 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs769131779, COSV54943309; called by muse, mutect2, varscan2
- TCN1 | c.1220G>T p.G407V | Missense Mutation (SNP) | VAF 62/411 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV57254326; called by muse, mutect2, varscan2
- TECPR2 | c.4178G>A p.S1393N | Missense Mutation (SNP) | VAF 31/359 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs757983805, COSV100850045; called by muse, mutect2
- TFAP2D | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 37/298 reads (12%) | catalogued as COSV50451898; called by muse, mutect2, varscan2
- TG | c.6396G>A p.S2132= | Splice Region (SNP) | VAF 46/339 reads (14%) | catalogued as rs371610789; called by muse, mutect2, varscan2
- THBS2 | c.2419G>A p.D807N | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.419); catalogued as rs1335785590; called by muse, mutect2
- TMEM132D | c.1477G>T p.G493W | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67158939; called by muse, mutect2
- TP53 | c.69G>A p.W23* | Nonsense Mutation (SNP) | VAF 26/340 reads (8%) | catalogued as COSV52932376, COSV53724279; called by muse, mutect2
- TRAPPC8 | c.3902C>T p.P1301L | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs781717239; called by muse, mutect2, varscan2
- VCAN | c.1226C>A p.T409K | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV99425969; called by muse, mutect2, varscan2
- ZDBF2 | c.6692C>G p.S2231C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100985152; called by muse, mutect2, varscan2
- ZIC1 | c.150C>A p.N50K | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.519); catalogued as COSV51550736; called by muse, mutect2, varscan2
- ZNF268 | c.2483G>T p.R828L | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV57213336; called by muse, varscan2
- ZNF407 | c.4050G>A p.M1350I | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1420265494; called by muse, varscan2
- ABCB5 | c.3584A>T p.Q1195L (on ENST00000404938 / NM_001163941.2; = p.Q750L on NM_178559.6) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- ABHD14A-ACY1 | c.932A>T p.Y311F | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ACOT4 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ACTN2 | c.2454G>T p.M818I | Missense Mutation (SNP) | VAF 177/626 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ADARB2 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- ADGB | c.863G>T p.W288L | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, varscan2
- ADORA1 | c.619A>G p.I207V | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- AEN | c.915G>C p.W305C | Missense Mutation (SNP) | VAF 67/355 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AFF2 | c.2934G>T p.K978N | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AKAP1 | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AKAP6 | c.6622G>A p.A2208T | Missense Mutation (SNP) | VAF 36/1038 reads (3%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); called by muse, mutect2
- AKR1C3 | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- AMER1 | c.2462_2480del p.K821Sfs*40 | Frame Shift Del (DEL) | VAF 24/109 reads (22%) | called by mutect2, pindel, varscan2
- AOC3 | c.118C>T p.H40Y | Missense Mutation (SNP) | VAF 41/239 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- AP4E1 | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 30/140 reads (21%) | called by muse, mutect2, varscan2
- ARL14EP | c.462dup p.T155Yfs*8 | Frame Shift Ins (INS) | VAF 48/170 reads (28%) | called by pindel, varscan2
- ASPSCR1 | c.1382A>G p.H461R | Missense Mutation (SNP) | VAF 83/210 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- AUNIP | c.188del p.R63Kfs*41 | Frame Shift Del (DEL) | VAF 17/67 reads (25%) | called by mutect2, pindel, varscan2
- BCAT1 | c.389C>A p.P130Q | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BLM | c.1379C>T p.S460L | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- BRD8 | c.2151G>T p.M717I (on ENST00000254900 / NM_139199.2; = p.M790I on NM_006696.4) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- C1orf74 | c.302G>T p.C101F | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CABS1 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- CADPS | c.1831G>T p.D611Y | Missense Mutation (SNP) | VAF 52/263 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPN7 | c.63C>A p.D21E | Missense Mutation (SNP) | VAF 74/256 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CARD16 | c.215G>T p.C72F | Missense Mutation (SNP) | VAF 80/211 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CASZ1 | c.4408G>T p.G1470W | Missense Mutation (SNP) | VAF 85/365 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CATSPERG | c.2232G>C p.K744N | Missense Mutation (SNP) | VAF 87/382 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CBX4 | c.972_976dup p.K326Sfs*81 | Frame Shift Ins (INS) | VAF 14/62 reads (23%) | called by pindel, varscan2
- CCDC158 | c.2395G>T p.E799* | Nonsense Mutation (SNP) | VAF 82/176 reads (47%) | called by muse, mutect2, varscan2
- CCNB1 | c.171G>T p.Q57H | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- CCT6B | c.719A>C p.E240A | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- CDH11 | c.1306G>T p.E436* | Nonsense Mutation (SNP) | VAF 48/121 reads (40%) | called by muse, mutect2, varscan2
- CDH26 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CDH7 | c.1727del p.N576Tfs*15 | Frame Shift Del (DEL) | VAF 143/495 reads (29%) | called by mutect2, pindel*, varscan2
- CDH9 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDRT15L2 | c.87G>T p.R29S | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- CEP135 | c.2014G>T p.V672L | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP85 | c.1252G>T p.A418S | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- CEP85 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- CFAP46 | c.5748C>A p.Y1916* | Nonsense Mutation (SNP) | VAF 150/347 reads (43%) | called by muse, mutect2, varscan2
- CILP2 | c.2329G>A p.A777T | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- COL14A1 | c.4125C>A p.C1375* | Nonsense Mutation (SNP) | VAF 21/421 reads (5%) | called by muse, mutect2
- COL3A1 | c.2423C>A p.P808H | Missense Mutation (SNP) | VAF 42/283 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- COMMD7 | c.585C>A p.S195R | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- CPN1 | c.829G>T p.D277Y | Missense Mutation (SNP) | VAF 186/390 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- CRYBA1 | c.532G>A p.G178R | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSNK1D | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 91/251 reads (36%) | called by muse, mutect2, varscan2
- CSPP1 | c.1107del p.M370Wfs*8 (on ENST00000676605; = p.M329Wfs*8 on NM_024790.6) | Frame Shift Del (DEL) | VAF 37/194 reads (19%) | called by mutect2, pindel, varscan2
- CYP4V2 | c.347A>G p.K116R | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- DDHD2 | c.352A>C p.K118Q | Missense Mutation (SNP) | VAF 82/160 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- DENND5B | c.3698G>T p.R1233L | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.421); called by muse, mutect2
- DIAPH3 | c.3562G>T p.A1188S | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DNAH7 | c.2505G>T p.K835N | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DOP1A | c.770A>T p.H257L | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DSP | c.5640G>T p.K1880N | Missense Mutation (SNP) | VAF 250/396 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- EEF1E1 | c.408G>C p.K136N | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EPHA4 | c.1448A>G p.Q483R | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EPRS1 | c.4396G>T p.D1466Y | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- EXOC7 | c.1600A>G p.T534A (on ENST00000335146 / NM_001145297.4; = p.T452A on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/247 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- F13A1 | c.106G>T p.V36L | Missense Mutation (SNP) | VAF 67/128 reads (52%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM131B | c.995A>T p.N332I | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAM81B | c.125-2A>T p.X42_splice | Splice Site (SNP) | VAF 40/212 reads (19%) | called by muse, mutect2, varscan2
- FHL5 | c.291G>T p.E97D | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, varscan2
- FNDC1 | c.4718C>T p.P1573L | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- FRG2B | c.4G>T p.G2* | Nonsense Mutation (SNP) | VAF 46/228 reads (20%) | called by muse, varscan2
- FRMD1 | c.1583A>T p.K528M | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- GC | c.1165G>T p.G389C | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- GFRA1 | c.1291A>G p.I431V | Missense Mutation (SNP) | VAF 153/307 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GFRA1 | c.139C>G p.R47G | Missense Mutation (SNP) | VAF 49/369 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GNPTAB | c.1967T>G p.I656R | Missense Mutation (SNP) | VAF 76/285 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GP9 | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRHPR | c.10G>T p.V4L | Missense Mutation (SNP) | VAF 571/859 reads (66%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GSTM5 | c.265del p.E89Rfs*35 | Frame Shift Del (DEL) | VAF 27/154 reads (18%) | called by mutect2, pindel, varscan2
- GTF2I | c.2609A>T p.E870V (on ENST00000573035 / NM_032999.4; = p.E829V on NM_001518.5) | Missense Mutation (SNP) | VAF 23/357 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- HCAR2 | c.117C>G p.I39M | Missense Mutation (SNP) | VAF 83/423 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- IL16 | c.565-2A>T p.X189_splice | Splice Site (SNP) | VAF 46/99 reads (46%) | called by muse, mutect2, varscan2
- INPP5J | c.707G>A p.R236K | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- INPP5J | c.1168G>C p.A390P | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- INSM1 | c.608C>A p.P203Q | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IPP | c.1194G>T p.W398C | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ITGBL1 | c.686G>C p.R229P | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ITPR2 | c.5881T>A p.C1961S | Missense Mutation (SNP) | VAF 27/563 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2
- KARS1 | c.415G>T p.G139W | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); called by muse, varscan2
- KCNS3 | c.498G>C p.Q166H | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KCNT2 | c.921del p.S308Hfs*2 | Frame Shift Del (DEL) | VAF 40/194 reads (21%) | called by pindel, varscan2
- KIF13A | c.1870T>A p.Y624N | Missense Mutation (SNP) | VAF 649/1075 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIF4B | c.2678C>A p.A893D | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by mutect2, varscan2
- KLHL33 | c.997G>T p.D333Y | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- KRT74 | c.1360T>C p.S454P | Missense Mutation (SNP) | VAF 89/264 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- KRT74 | c.793G>T p.V265L | Missense Mutation (SNP) | VAF 145/350 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- LIFR | c.3189del p.N1064Ifs*6 | Frame Shift Del (DEL) | VAF 32/114 reads (28%) | called by mutect2, pindel, varscan2
- LILRB1 | c.1471+1G>T p.X491_splice (on ENST00000427581; = p.X454_splice on NM_006669.6) | Splice Site (SNP) | VAF 16/137 reads (12%) | called by muse, mutect2, varscan2
- LIM2 | c.175+3G>A | Splice Region (SNP) | VAF 145/357 reads (41%) | called by muse, mutect2, varscan2
- LONRF3 | c.1309A>G p.K437E (on ENST00000371628 / NM_001031855.3; = p.K396E on NM_024778.5) | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- LOXHD1 | c.5708C>T p.A1903V (on ENST00000642948; = p.A1841V on NM_144612.7) | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP5 | c.4573G>T p.A1525S | Missense Mutation (SNP) | VAF 132/473 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- LSR | c.9G>T p.Q3H | Missense Mutation (SNP) | VAF 56/245 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- MACC1 | c.1426G>T p.E476* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- MAU2 | c.187A>G p.I63V | Missense Mutation (SNP) | VAF 155/337 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MSI1 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 47/251 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MTA1 | c.1280A>G p.Y427C | Missense Mutation (SNP) | VAF 54/293 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- MUC17 | c.3858C>A p.S1286R | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- NBAS | c.288-1G>C p.X96_splice | Splice Site (SNP) | VAF 50/206 reads (24%) | called by muse, mutect2, varscan2
- NFS1 | c.97+8C>G | Splice Region (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- NLGN4Y | c.2081C>T p.A694V | Missense Mutation (SNP) | VAF 81/296 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NPHS2 | c.795-2A>T p.X265_splice | Splice Site (SNP) | VAF 29/491 reads (6%) | called by muse, mutect2
- OIT3 | c.790G>C p.V264L | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- OR2AT4 | c.29T>C p.V10A | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.006); called by muse, mutect2
- OR4K5 | c.524A>T p.D175V | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OTOL1 | c.1318del p.Q440Kfs*? | Frame Shift Del (DEL) | VAF 39/189 reads (21%) | called by mutect2, pindel, varscan2
- PCLO | c.5978T>C p.I1993T | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- PCNX2 | c.5551G>T p.G1851* | Nonsense Mutation (SNP) | VAF 32/99 reads (32%) | called by muse, mutect2, varscan2
- PEG3 | c.2877A>C p.E959D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- PGK1 | c.520A>T p.S174C | Missense Mutation (SNP) | VAF 80/136 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PHLDB3 | c.917G>C p.R306P | Missense Mutation (SNP) | VAF 98/240 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); called by muse, varscan2
- PHLPP1 | c.4630G>T p.G1544C | Missense Mutation (SNP) | VAF 85/244 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIEZO2 | c.378C>A p.D126E | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- PIK3CD | c.2450C>G p.P817R | Missense Mutation (SNP) | VAF 81/270 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- PLA2G3 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 66/304 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLB1 | c.2089-1G>T p.X697_splice | Splice Site (SNP) | VAF 144/373 reads (39%) | called by muse, mutect2, varscan2
- PLCE1 | c.4332_4339del p.D1445Afs*20 | Frame Shift Del (DEL) | VAF 51/426 reads (12%) | called by mutect2, pindel
- PLEKHM3 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- PRAMEF4 | c.727del p.H243Tfs*35 | Frame Shift Del (DEL) | VAF 90/392 reads (23%) | called by mutect2, pindel, varscan2
- PRKCH | c.772T>A p.F258I | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.108); called by muse, varscan2
- PRR16 | c.481G>T p.G161C (on ENST00000407149 / NM_001300783.2; = p.G138C on NM_016644.2) | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- PSG2 | c.510T>G p.D170E | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- RHO | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RIPK2 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, varscan2
- RNASE2 | c.64del p.E22Rfs*24 | Frame Shift Del (DEL) | VAF 14/66 reads (21%) | called by mutect2, pindel, varscan2
- ROBO2 | c.2785C>A p.P929T | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ROCK1 | c.2584del p.E862Nfs*14 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | called by mutect2, pindel, varscan2
- RSBN1L | c.2434G>T p.D812Y | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.847); called by muse, varscan2
- RYR2 | c.7253G>T p.R2418I | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCUBE1 | c.2317T>C p.C773R | Missense Mutation (SNP) | VAF 80/362 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA5B | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- SGK3 | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- SLC38A10 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 105/257 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC44A2 | c.1996_1997dup p.L667Rfs*31 | Frame Shift Ins (INS) | VAF 45/318 reads (14%) | called by mutect2, pindel, varscan2
- SLIT1 | c.3661G>A p.V1221M | Missense Mutation (SNP) | VAF 171/425 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SNTG1 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 88/328 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SOHLH2 | c.298G>T p.V100F | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- STXBP5L | c.2273G>T p.S758I | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- TEX11 | c.1348G>T p.D450Y (on ENST00000344304; = p.D435Y on NM_031276.3) | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- TEX47 | c.629del p.P210Qfs*5 | Frame Shift Del (DEL) | VAF 12/111 reads (11%) | called by mutect2, pindel, varscan2
- TMEM131 | c.3754G>T p.A1252S | Missense Mutation (SNP) | VAF 90/305 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TMPRSS11F | c.1195G>T p.D399Y | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); called by muse, varscan2
- TRIM52 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TRIM58 | c.74A>T p.E25V | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- TRIM64C | c.16C>A p.L6M | Missense Mutation (SNP) | VAF 75/203 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- TRRAP | c.6322-1G>A p.X2108_splice (on ENST00000359863 / NM_001244580.1; = p.X2090_splice on NM_003496.3) | Splice Site (SNP) | VAF 22/99 reads (22%) | called by muse, mutect2, varscan2
- UBXN2A | c.41+1del | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
- USP15 | c.1350G>T p.E450D (on ENST00000280377 / NM_001351159.2; = p.E421D on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.157); called by muse, varscan2
- VSX1 | c.628G>C p.V210L | Missense Mutation (SNP) | VAF 53/348 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR97 | c.2260C>G p.L754V | Missense Mutation (SNP) | VAF 397/656 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- YTHDF3 | c.1754A>C p.Q585P | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- ZFHX4 | c.1802C>A p.P601Q | Missense Mutation (SNP) | VAF 37/354 reads (10%) | SIFT tolerated, low confidence (0.53); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ZIC3 | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF223 | c.427A>T p.T143S | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF254 | c.1030C>G p.H344D | Missense Mutation (SNP) | VAF 81/225 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF496 | c.1107del p.Y370Tfs*85 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- ZNF646 | c.193A>T p.N65Y | Missense Mutation (SNP) | VAF 77/116 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF681 | c.1115del p.G372Afs*15 | Frame Shift Del (DEL) | VAF 25/180 reads (14%) | called by mutect2, varscan2
- ABCA8 | c.297G>T p.L99= | Silent (SNP) | VAF 32/98 reads (33%) | called by muse, mutect2
- ABCC9 | c.2892T>C p.D964= | Silent (SNP) | VAF 25/230 reads (11%) | called by muse, mutect2, varscan2
- ABCC9 | c.2455A>C p.R819= | Silent (SNP) | VAF 128/669 reads (19%) | called by muse, varscan2
- AGAP3 | c.1461G>T p.P487= (on ENST00000622464; = p.P523= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/198 reads (28%) | called by muse, mutect2, varscan2
- ARHGAP33 | c.2034G>C p.L678= | Silent (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- ARHGEF1 | c.2529A>G p.E843= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- ATP13A2 | c.2310G>A p.Q770= | Silent (SNP) | VAF 52/237 reads (22%) | catalogued as rs764319654; called by muse, mutect2, varscan2
- CACNA1G | c.3727C>A p.R1243= | Silent (SNP) | VAF 92/243 reads (38%) | catalogued as COSV61720278; called by muse, mutect2, varscan2
- CALHM6 | c.18G>T p.A6= | Silent (SNP) | VAF 37/63 reads (59%) | catalogued as COSV63991728; called by muse, mutect2, varscan2
- CASS4 | c.2334G>T p.T778= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs755377297; called by muse, mutect2, varscan2
- CAST | c.42C>A p.P14= | Silent (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- CCDC167 | c.270C>T p.L90= | Silent (SNP) | VAF 151/610 reads (25%) | catalogued as rs767172012, COSV64982842; called by muse, varscan2
- CDH7 | c.2013G>C p.L671= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs776786253; called by muse, mutect2, varscan2
- CDH9 | c.807C>A p.P269= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV99152223; called by muse, mutect2, varscan2
- CHAT | c.1749C>A p.A583= | Silent (SNP) | VAF 101/529 reads (19%) | catalogued as COSV60328568; called by muse, varscan2
- CHMP4B | c.141C>A p.I47= | Silent (SNP) | VAF 108/329 reads (33%) | catalogued as COSV54135379; called by muse, mutect2, varscan2
- CNGA3 | c.1110A>G p.P370= | Silent (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2
- COL20A1 | c.1827C>A p.T609= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV58926425; called by muse, mutect2
- DIAPH3 | c.3561G>T p.L1187= | Silent (SNP) | VAF 38/102 reads (37%) | called by muse, mutect2, varscan2
- DISP3 | c.139C>A p.R47= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as rs373256766; called by muse, mutect2, varscan2
- DPP6 | c.1818G>T p.L606= (on ENST00000377770 / NM_001364500.2; = p.L544= on NM_001936.5) | Silent (SNP) | VAF 31/119 reads (26%) | called by muse, mutect2, varscan2
- EML6 | c.1161C>T p.D387= | Silent (SNP) | VAF 144/383 reads (38%) | catalogued as rs553753088; called by muse, mutect2, varscan2
- ERCC6 | c.3381G>A p.G1127= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs1410419880; called by muse, varscan2
- EYA1 | c.1401G>A p.L467= | Silent (SNP) | VAF 92/662 reads (14%) | catalogued as COSV58171981; called by muse, mutect2, varscan2
- FCAR | c.714C>T p.L238= | Silent (SNP) | VAF 53/327 reads (16%) | catalogued as rs944126574, COSV62029084; called by muse, mutect2, varscan2
- FCGR3A | c.441C>A p.G147= | Silent (SNP) | VAF 157/540 reads (29%) | called by muse, mutect2, varscan2
- FCN2 | c.552C>A p.T184= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as COSV52477628; called by muse, mutect2, varscan2
- GABRG3 | c.624G>C p.V208= | Silent (SNP) | VAF 65/127 reads (51%) | catalogued as COSV61530400; called by muse, mutect2, varscan2
- GOLM1 | c.274C>T p.L92= | Silent (SNP) | VAF 40/164 reads (24%) | catalogued as rs760057943; called by muse, mutect2, varscan2
- GPT | c.966C>T p.F322= | Silent (SNP) | VAF 22/168 reads (13%) | called by mutect2, varscan2
- HCRTR2 | c.744C>A p.R248= | Silent (SNP) | VAF 23/69 reads (33%) | called by muse, mutect2, varscan2
- HERC1 | c.771A>G p.Q257= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as rs778004106; called by muse, mutect2, varscan2
- IDI1 | c.129G>A p.R43= | Silent (SNP) | VAF 51/233 reads (22%) | catalogued as rs1159791261; called by muse, mutect2, varscan2
- IGLV1-40 | c.355T>A p.*119= | Silent (SNP) | VAF 28/133 reads (21%) | called by muse, mutect2, varscan2
- INA | c.453C>G p.R151= | Silent (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- IRAK2 | c.912G>T p.S304= | Silent (SNP) | VAF 81/282 reads (29%) | called by muse, mutect2, varscan2
- KIF21A | c.3414A>C p.S1138= (on ENST00000361418 / NM_001378440.1; = p.S1125= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/279 reads (8%) | called by muse, mutect2
- KPRP | c.1390C>T p.L464= | Silent (SNP) | VAF 82/251 reads (33%) | called by muse, mutect2, varscan2
- LRP2 | c.2631C>T p.I877= | Silent (SNP) | VAF 93/225 reads (41%) | catalogued as rs139833815; called by muse, mutect2, varscan2
- MTPN | c.69C>T p.A23= | Silent (SNP) | VAF 77/223 reads (35%) | called by muse, mutect2, varscan2
- MYH13 | c.3075C>A p.I1025= | Silent (SNP) | VAF 13/95 reads (14%) | called by muse, mutect2, varscan2
- NAV2 | c.1656G>T p.V552= (on ENST00000396087 / NM_001244963.2; = p.V529= on NM_145117.5) | Silent (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- NBEAL1 | c.1596G>A p.L532= | Silent (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
- NCKAP5 | c.5460A>G p.Q1820= | Silent (SNP) | VAF 92/189 reads (49%) | called by muse, mutect2, varscan2
- NOP53 | c.1119G>A p.G373= | Silent (SNP) | VAF 68/181 reads (38%) | called by muse, mutect2, varscan2
- NPR3 | c.1579C>A p.R527= (on ENST00000265074 / NM_001364458.2; = p.R526= on NM_000908.4) | Silent (SNP) | VAF 47/233 reads (20%) | called by muse, mutect2, varscan2
- NTRK2 | c.894C>T p.D298= | Silent (SNP) | VAF 29/154 reads (19%) | catalogued as rs1355744801; called by muse, mutect2, varscan2
- OR2M5 | c.366C>A p.R122= | Silent (SNP) | VAF 63/243 reads (26%) | called by muse, mutect2, varscan2
- OR2T3 | c.609C>G p.L203= | Silent (SNP) | VAF 84/291 reads (29%) | catalogued as rs1421342740, COSV62082908; called by muse, mutect2, varscan2
- OR51I2 | c.240T>A p.T80= | Silent (SNP) | VAF 22/72 reads (31%) | called by muse, mutect2, varscan2
- OR51V1 | c.252G>T p.V84= | Silent (SNP) | VAF 27/93 reads (29%) | called by muse, mutect2, varscan2
- OR52J3 | c.873C>T p.I291= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs1483231053, COSV66747237; called by muse, mutect2, varscan2
- OR5H14 | c.78C>T p.P26= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as COSV101454214; called by muse, mutect2, varscan2
- P2RY2 | c.303C>T p.F101= | Silent (SNP) | VAF 37/264 reads (14%) | catalogued as COSV100232895; called by muse, mutect2, varscan2
- PABPC5 | c.381T>C p.S127= | Silent (SNP) | VAF 61/134 reads (46%) | catalogued as rs751905642; called by muse, mutect2, varscan2
- PCDH15 | c.5649C>A p.L1883= | Silent (SNP) | VAF 46/334 reads (14%) | called by muse, mutect2, varscan2
- PIGS | c.1278G>C p.L426= | Silent (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- PLEKHG7 | c.399C>A p.L133= | Silent (SNP) | VAF 100/416 reads (24%) | catalogued as COSV67337736; called by muse, mutect2, varscan2
- PPP1R26 | c.3228G>T p.A1076= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as rs779037774; called by muse, mutect2
- PRCC | c.255C>T p.F85= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV99071919; called by muse, mutect2, varscan2
- PROKR2 | c.807C>T p.C269= | Silent (SNP) | VAF 80/438 reads (18%) | called by muse, mutect2, varscan2
- PTPN14 | c.3138G>T p.T1046= | Silent (SNP) | VAF 96/353 reads (27%) | catalogued as rs372350429; called by muse, mutect2, varscan2
- PXDNL | c.2841G>A p.Q947= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs201891697; called by muse, mutect2
- RBMXL2 | c.936G>T p.R312= | Silent (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- RND1 | c.93A>G p.Q31= | Silent (SNP) | VAF 53/160 reads (33%) | called by muse, mutect2, varscan2
- RPH3A | c.282G>A p.G94= (on ENST00000389385 / NM_001143854.2; = p.G90= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/280 reads (19%) | called by muse, varscan2
- RSPH6A | c.1431G>A p.E477= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as rs1046585805; called by muse, mutect2
- RTL1 | c.1839C>T p.T613= | Silent (SNP) | VAF 42/252 reads (17%) | catalogued as rs769810308, COSV66017042; called by muse, mutect2, varscan2
- SLC35F4 | c.1368C>A p.R456= (on ENST00000339762 / NM_001352015.2; = p.R420= on NM_001206920.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as COSV60265217; called by muse, varscan2
- SPATA31D1 | c.4395C>T p.S1465= | Silent (SNP) | VAF 73/153 reads (48%) | catalogued as rs761473977; called by muse, mutect2, varscan2
- SPPL2C | c.1413C>A p.I471= | Silent (SNP) | VAF 40/250 reads (16%) | called by muse, mutect2, varscan2
- STAB2 | c.2745G>A p.L915= | Silent (SNP) | VAF 70/294 reads (24%) | called by muse, mutect2, varscan2
- SULT1C4 | c.714C>G p.V238= | Silent (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- TMEM132D | c.1479G>T p.G493= | Silent (SNP) | VAF 30/118 reads (25%) | catalogued as COSV101243022; called by muse, mutect2
- TMEM151A | c.474C>T p.Y158= | Silent (SNP) | VAF 39/137 reads (28%) | catalogued as COSV59175349; called by muse, mutect2, varscan2
- UPB1 | c.60C>T p.P20= | Silent (SNP) | VAF 54/294 reads (18%) | catalogued as rs752771871; called by muse, mutect2, varscan2
- USP29 | c.1119T>A p.A373= | Silent (SNP) | VAF 20/121 reads (17%) | called by muse, mutect2, varscan2
- VPS13B | c.1887G>T p.V629= | Silent (SNP) | VAF 70/138 reads (51%) | called by muse, mutect2
- VWA5B1 | c.1482C>A p.P494= | Silent (SNP) | VAF 67/234 reads (29%) | called by muse, mutect2, varscan2
- ZBTB40 | c.2433C>T p.L811= | Silent (SNP) | VAF 47/240 reads (20%) | catalogued as COSV65145484; called by muse, varscan2
- ZFAT | c.3657G>A p.E1219= | Silent (SNP) | VAF 82/1008 reads (8%) | catalogued as rs1360571725; called by muse, mutect2
- ZGRF1 | c.5334C>G p.T1778= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV101500687; called by muse, varscan2
- ZNRF4 | c.756G>T p.L252= | Silent (SNP) | VAF 128/254 reads (50%) | called by muse, mutect2, varscan2
- AC009039.2 | chr16:52084308 G>T | 5'Flank (SNP) | VAF 126/282 reads (45%) | called by muse, mutect2, varscan2
- ACADL | c.372-33A>G | Intron (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- ACTG1 | chr17:81512802 C>G | 5'Flank (SNP) | VAF 18/102 reads (18%) | catalogued as rs1156369373; called by muse, mutect2, varscan2
- ADAMTS16 | c.-13G>A | 5'UTR (SNP) | VAF 22/152 reads (14%) | called by muse, mutect2, varscan2
- AGBL3 | c.2110+12738A>G | Intron (SNP) | VAF 32/145 reads (22%) | catalogued as rs894229092; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849923 T>C | 5'Flank (SNP) | VAF 41/73 reads (56%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73850771 G>T | 3'Flank (SNP) | VAF 28/46 reads (61%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130916253 C>A | 5'Flank (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- ATP1A3 | c.3052+80C>A | Intron (SNP) | VAF 42/271 reads (15%) | called by muse, mutect2, varscan2
- AWAT2 | c.648-33C>A | Intron (SNP) | VAF 54/200 reads (27%) | called by muse, mutect2, varscan2
- BLK | c.*260A>C | 3'UTR (SNP) | VAF 51/84 reads (61%) | catalogued as rs1432287238; called by muse, mutect2, varscan2
- CALM3 | c.3+703G>A | Intron (SNP) | VAF 56/338 reads (17%) | called by muse, mutect2, varscan2
- CASP7 | c.111-11610G>A | Intron (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2, varscan2
- CCDC167 | c.*69C>G | 3'UTR (SNP) | VAF 97/386 reads (25%) | called by muse, varscan2
- CYP2B7P | n.280G>T | RNA (SNP) | VAF 145/383 reads (38%) | called by muse, mutect2, varscan2
- DIO3 | chr14:101557704 G>T | 5'Flank (SNP) | VAF 53/136 reads (39%) | called by muse, mutect2, varscan2
- DNAH14 | c.5468-1632G>C | Intron (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- DNAI4 | c.345+20G>T | Intron (SNP) | VAF 5/8 reads (63%) | called by muse, mutect2, varscan2
- ECM1 | c.708+23G>T | Intron (SNP) | VAF 72/286 reads (25%) | called by muse, mutect2, varscan2
- ELMOD1 | c.-86+402C>T | Intron (SNP) | VAF 74/163 reads (45%) | catalogued as rs1253888130; called by muse, mutect2, varscan2
- FPR3 | c.-1G>C | 5'UTR (SNP) | VAF 5/26 reads (19%) | called by muse, varscan2
- GABARAPL2 | c.-16C>G | 5'UTR (SNP) | VAF 38/137 reads (28%) | called by muse, mutect2, varscan2
- JPH2 | c.379+8427C>T | Intron (SNP) | VAF 32/141 reads (23%) | called by muse, mutect2, varscan2
- KRT6A | c.1077+19G>T | Intron (SNP) | VAF 76/510 reads (15%) | catalogued as rs1452466298; called by muse, mutect2, varscan2
- LEPR | c.2673+38G>T | Intron (SNP) | VAF 20/92 reads (22%) | called by muse, varscan2
- LINC02877 | n.590C>G | RNA (SNP) | VAF 10/64 reads (16%) | catalogued as rs1294744095; called by muse, mutect2, varscan2
- NCAM1 | c.2457-1612C>A | Intron (SNP) | VAF 32/111 reads (29%) | catalogued as COSV100377084; called by muse, mutect2, varscan2
- NOS3 | c.1752+1410G>C | Intron (SNP) | VAF 35/161 reads (22%) | catalogued as COSV52488858, COSV52497183; called by muse, mutect2, varscan2
- NPC2 | chr14:74494172 G>T | 5'Flank (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- NUDCD3 | c.509+16860G>T | Intron (SNP) | VAF 95/491 reads (19%) | catalogued as rs952589861; called by muse, mutect2, varscan2
- OR10AB1P | n.1369del | RNA (DEL) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- PCDHB6 | chr5:141156374 G>T | 3'Flank (SNP) | VAF 34/78 reads (44%) | called by muse, mutect2, varscan2
- PLVAP | c.*43G>A | 3'UTR (SNP) | VAF 10/147 reads (7%) | catalogued as rs1299608689; called by muse, mutect2
- PTPRO | c.-42C>A | 5'UTR (SNP) | VAF 49/475 reads (10%) | called by muse, mutect2, varscan2
- RTBDN | c.462+214C>A | Intron (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- SPANXN1 | c.-29C>A | 5'UTR (SNP) | VAF 107/173 reads (62%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.1164G>T | RNA (SNP) | VAF 111/273 reads (41%) | called by muse, mutect2, varscan2
- SYT7 | c.215+5147C>T | Intron (SNP) | VAF 8/31 reads (26%) | catalogued as rs747272902, COSV55659802; called by muse, mutect2, varscan2
- TMC2 | c.-2C>A | 5'UTR (SNP) | VAF 85/340 reads (25%) | called by muse, mutect2, varscan2
- TRIM8 | c.*577C>G | 3'UTR (SNP) | VAF 22/320 reads (7%) | catalogued as COSV100193337; called by muse, mutect2
- TRNT1 | c.149-557G>T | Intron (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- ZIC2 | c.*357G>A | 3'UTR (SNP) | VAF 62/219 reads (28%) | catalogued as rs926212422; called by muse, mutect2, varscan2
- ZNF195 | c.227-139G>C | Intron (SNP) | VAF 26/85 reads (31%) | called by muse, mutect2, varscan2
- ZNF451 | c.-13G>T | 5'UTR (SNP) | VAF 95/285 reads (33%) | catalogued as rs367768959, COSV100675015; called by muse, mutect2, varscan2
- ZNF827 | c.*365G>A | 3'UTR (SNP) | VAF 66/348 reads (19%) | catalogued as rs773061032; called by muse, mutect2, varscan2
- ZNF849P | n.1065C>A | RNA (SNP) | VAF 96/218 reads (44%) | called by muse, varscan2
